Somatic mutation profile of tumor specimen ALCH-B570-TTP1-A (aliquot ALCH-B570-TTP1-A-1-0-D-A85H-36) from ALCHEMIST case ALCH-B570, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 77.1 years (28,167 days).
Specimen ALCH-B570-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 78424713-01fc-4b0f-82eb-1be91a33fb23.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B570-NB1-A (Blood Derived Normal), aliquot ALCH-B570-NB1-A-1-0-D-A85H-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/301393d9-0c64-434f-bf79-3fa37e06e628

The open-access MAF lists 37 somatic variants for this specimen: 23 protein-altering or splice-affecting, 9 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 9, Intron 3, Splice Site 1, RNA 1, 3'UTR 1, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CYP3A5 | c.83G>A p.R28H | Missense Mutation (SNP) | VAF 47/398 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs769315225, COSV56119799; called by muse, mutect2, varscan2
- DBX2 | c.829C>A p.P277T | Missense Mutation (SNP) | VAF 18/137 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as rs1295488585, COSV100224550; called by muse, mutect2, varscan2
- DIAPH1 | c.3274-1C>T p.X1092_splice | Splice Site (SNP) | VAF 98/520 reads (19%) | catalogued as COSV53880835; called by muse, mutect2, varscan2
- EPHA6 | c.2135C>A p.A712E (on ENST00000389672 / NM_001080448.3; = p.A104E on NM_173655.4) | Missense Mutation (SNP) | VAF 16/253 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1470302342, COSV67599534; called by muse, mutect2
- KDM5C | c.4486del p.E1496Kfs*48 | Frame Shift Del (DEL) | VAF 18/181 reads (10%) | catalogued as COSV64768546; called by pindel, varscan2
- KIAA1210 | c.3560C>T p.P1187L | Missense Mutation (SNP) | VAF 32/287 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs776362608, COSV101273846, COSV68178059; called by muse, mutect2, varscan2
- PCDHA2 | c.1745C>T p.P582L | Missense Mutation (SNP) | VAF 28/263 reads (11%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.052); catalogued as COSV65364258, COSV65365396; called by muse, mutect2, varscan2
- SEMG1 | c.292C>T p.R98* | Nonsense Mutation (SNP) | VAF 20/127 reads (16%) | catalogued as rs376380754, COSV104390102; called by muse, mutect2, varscan2
- SLC2A3 | c.241G>A p.V81I | Missense Mutation (SNP) | VAF 29/190 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.19); catalogued as rs759843926, COSV50005639; called by muse, mutect2, varscan2
- TAS2R46 | c.379A>G p.S127G | Missense Mutation (SNP) | VAF 28/250 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.073); catalogued as rs370679216; called by muse, varscan2
- ABCB4 | c.2831C>T p.S944L | Missense Mutation (SNP) | VAF 28/429 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.392); called by muse, mutect2
- AC008397.2 | c.772G>A p.V258M | Missense Mutation (SNP) | VAF 20/192 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- ACTC1 | c.515C>A p.A172D | Missense Mutation (SNP) | VAF 58/446 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- CYP51A1 | c.513A>G p.I171M | Missense Mutation (SNP) | VAF 103/485 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.684); called by muse, mutect2, varscan2
- EIF4G3 | c.2115A>T p.Q705H | Missense Mutation (SNP) | VAF 44/258 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- EML5 | c.994G>T p.A332S | Missense Mutation (SNP) | VAF 58/604 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.506); called by muse, mutect2
- HARS1 | c.1459G>T p.V487L | Missense Mutation (SNP) | VAF 24/394 reads (6%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.645); called by muse, mutect2
- PRUNE2 | c.3806C>T p.A1269V | Missense Mutation (SNP) | VAF 19/481 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2
- PTPRA | c.1900G>C p.E634Q | Missense Mutation (SNP) | VAF 15/215 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.222); called by muse, mutect2
- UBC | c.1846C>G p.L616V | Missense Mutation (SNP) | VAF 64/554 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.056); called by muse, varscan2
- USP27X | c.352C>T p.P118S | Missense Mutation (SNP) | VAF 48/278 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- VCAN | c.4807C>G p.L1603V | Missense Mutation (SNP) | VAF 78/800 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.03); called by muse, mutect2
- ZMYM1 | c.178T>G p.L60V | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.189); called by muse, mutect2, varscan2
- CEACAM8 | c.900C>T p.H300= | Silent (SNP) | VAF 41/383 reads (11%) | called by muse, mutect2, varscan2
- HMG20B | c.894C>T p.H298= | Silent (SNP) | VAF 10/105 reads (10%) | catalogued as rs779840515, COSV53572639; called by muse, mutect2, varscan2
- NBR1 | c.2697C>T p.A899= | Silent (SNP) | VAF 16/148 reads (11%) | called by muse, mutect2, varscan2
- PGBD2 | c.1674C>T p.D558= | Silent (SNP) | VAF 22/101 reads (22%) | called by muse, mutect2, varscan2
- PLCXD2 | c.51C>T p.C17= | Silent (SNP) | VAF 21/190 reads (11%) | catalogued as rs1262909215; called by mutect2, varscan2
- RAD21 | c.606G>A p.L202= | Silent (SNP) | VAF 20/344 reads (6%) | catalogued as rs139128240, COSV52061078; called by muse, mutect2
- RTL1 | c.1692C>T p.D564= | Silent (SNP) | VAF 10/86 reads (12%) | catalogued as COSV66016913; called by muse, mutect2, varscan2
- SRP54 | c.177T>C p.A59= | Silent (SNP) | VAF 12/145 reads (8%) | catalogued as COSV53741626; called by muse, mutect2
- ZNF257 | c.879C>G p.A293= | Silent (SNP) | VAF 42/410 reads (10%) | called by muse, mutect2, varscan2
- AP001122.1 | n.412G>A | RNA (SNP) | VAF 6/62 reads (10%) | called by mutect2, varscan2
- CFAP77 | c.632+13700C>T | Intron (SNP) | VAF 20/148 reads (14%) | called by muse, mutect2, varscan2
- GPATCH8 | c.*1599C>T | 3'UTR (SNP) | VAF 12/190 reads (6%) | called by muse, mutect2
- MEMO1 | c.62-19859C>T | Intron (SNP) | VAF 12/118 reads (10%) | called by muse, mutect2, varscan2
- ZEB2 | c.332-45G>T | Intron (SNP) | VAF 37/219 reads (17%) | called by muse, mutect2, varscan2
